Gene-level copy-number profile of tumor specimen TCGA-AG-4001-01A from TCGA case TCGA-AG-4001, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.7 years (27,302 days).
Specimen TCGA-AG-4001-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.ae195126-bf08-411b-a1f5-976ed9f209af.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-4001-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/55730be0-ebdd-4e25-9304-67fadbccfa29

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,097; copy number 2: 4,829; copy number 3: 21,799; copy number 4: 8,860; copy number 5: 9,834; copy number 6: 7,256; copy number 7: 3,246; copy number 8: 814; copy number 9: 1,384; copy number 11: 689.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-4001-01A-02D-1428-01): tumor purity 0.48, ploidy 3.88, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 6,133 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–2,871,231, 46 genes, copy number 7: FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN, MYT1L, AC093390.2, AC093390.1, MYT1L-AS1, AC018685.2, AC018685.3, AC011995.2, AC018685.1, AC011995.1.
- chr2:44,361,947–110,716,595, 1,294 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr7:70,972–63,054,431, 1,081 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).
- chr8:99,960,936–100,131,268, 1 gene, copy number 9 (within-gene range 5–9): RGS22.
- chr8:100,133,351–106,752,694, 134 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr8:119,350,291–128,220,803, 155 genes, copy number 7 (broad region; genes not listed).
- chr8:139,600,838–141,786,313, 38 genes, copy number 8 (within-gene range 6–8): KCNK9, TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.2, AC138647.1, AC025839.1, MIR1302-7.
- chr9:14,475–43,045,120, 776 genes, copy number 8 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 7 (broad region; genes not listed).
- chr14:22,123,318–22,518,871, 69 genes, copy number 7 (broad region; genes not listed).
- chr20:16,857,962–64,313,132, 1,148 genes, copy number 7–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,097. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
